Gene-level copy-number profile of tumor specimen TCGA-L5-A43J-01A from TCGA case TCGA-L5-A43J, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-L5-A43J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.ed1da30f-bab0-409e-8f55-66aaa1199940.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A43J-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 833 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b6a923c3-fe1a-4710-bd40-f573ed4510dc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 144; copy number 1: 1,620; copy number 2: 11,829; copy number 3: 21,309; copy number 4: 17,806; copy number 5: 2,262; copy number 6: 1,271; copy number 7: 831; copy number 8: 1,308; copy number 9: 1,283; copy number 10: 127.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A43J-01A-12D-A246-01): tumor purity 0.64, ploidy 3.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 144 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:36,826,819–37,440,186, 21 genes (within-gene range 0–2): TRANK1, AC011816.1, RNU6ATAC4P, AC011816.2, PRADC1P1, EPM2AIP1, MLH1, RPL29P11, LRRFIP2, Y_RNA, UBE2D3P2, RNU6-1301P, UBE2FP1, AC126118.1, AC097359.1, AC097359.3, AC097359.2, GOLGA4, TCEA1P2, RNA5SP129, C3orf35.
- chr9:21,966,929–22,128,103, 7 genes (within-gene range 0–4): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr19:42,268,537–44,725,217, 116 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,549 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:187,668,912–189,325,304, 20 genes, copy number 7: SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2.
- chr3:189,645,327–189,645,466, 1 gene, copy number 7: AC078809.1.
- chr4:35,487,812–36,392,410, 7 genes, copy number 8 (within-gene range 4–8): SEC63P2, RNU6-573P, ARAP2, AC098827.1, AC104078.1, DTHD1, AC104078.2.
- chr5:58,198–45,895,970, 710 genes, copy number 9–10 (broad region; genes not listed).
- chr5:165,129,307–166,382,599, 9 genes, copy number 7: AC091973.1, LINC01938, AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1.
- chr7:107,580,246–108,569,666, 18 genes, copy number 8 (within-gene range 5–8): BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 8–10 (within-gene range 6–10) (broad region; genes not listed).
- chr11:64,778,954–67,639,560, 210 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr13:113,399,610–114,132,623, 23 genes, copy number 7: ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46, RASA3, RASA3-IT1.
- chr14:82,429,872–82,430,156, 1 gene, copy number 7: Metazoa_SRP.
- chr14:83,750,384–106,875,071, 777 genes, copy number 7 (broad region; genes not listed).
- chr20:16,272,104–26,251,546, 239 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 940. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
